Gene-level copy-number profile of tumor specimen TCGA-EO-A3B1-01A from TCGA case TCGA-EO-A3B1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 63.4 years (23,162 days).
Specimen TCGA-EO-A3B1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.fb17e0c7-b2e5-4db8-870b-3937e2432699.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EO-A3B1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f9b86af9-fc8d-4408-a490-831f97569d21

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 1,929; copy number 2: 13,582; copy number 3: 19,157; copy number 4: 18,576; copy number 5: 4,487; copy number 6: 675; copy number 7: 580; copy number 8: 448; copy number 9: 86; copy number 10: 116; copy number 11: 97; copy number 12: 53; copy number 15: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EO-A3B1-01A-12D-A19X-01): tumor purity 0.49, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:131,347,470–131,597,115, 9 genes: LINC02370, AC140118.2, AC140118.1, AC073578.4, AC073578.2, AC073578.5, AC073578.1, AC073578.3, AC140063.1.
- chr15:23,562,062–24,090,821, 8 genes: MIR4508, MKRN3, AC126407.1, MAGEL2, NDN, AC087490.1, RNU6-741P, PWRN4.
- chr15:24,162,754–24,343,464, 4 genes: PWRN2, AC087463.1, AC087463.2, AC087463.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 363 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:74,151,202–78,697,022, 76 genes, copy number 10–15 (within-gene range 7–15) (broad region; genes not listed).
- chr10:83,067,962–86,756,298, 49 genes, copy number 9: RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5, AL358787.2, LINC01519, AL358787.1, LINC02647, AC025428.1, LINC01520, AL731532.1, RNU6-325P, AL731532.2, GRID1-AS1, GRID1, AC022028.3, AC022028.2, RN7SKP238, AC022028.1, RNA5SP322, MIR346, AL844892.2, AL844892.1, WAPL, RNU6-780P, AL731569.1, RPL7AP8, OPN4, LDB3, AC067750.1.
- chr10:91,544,852–91,545,098, 1 gene, copy number 9: RPS27P1.
- chr12:459,939–3,072,145, 64 genes, copy number 11 (broad region; genes not listed).
- chr12:18,080,869–28,581,511, 173 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,929. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
